Somatic mutation profile of tumor specimen MBCProject_0067_T1_WES (aliquot MBCProject_0067_T1_WES_1) from CMI case MBCProject_0067, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 48.8 years (17,835 days).
Specimen MBCProject_0067_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62a9de19-3ff9-450b-a4ef-224d6fe78648.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0067_SALIVA (Saliva), aliquot MBCProject_0067_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fdb5db0-bef0-4652-92f9-6ba7139e61f7

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 4, Frame Shift Ins 3, 5'UTR 1, Intron 1, 5'Flank 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs201105250, COSV61362457; called by muse, mutect2, varscan2
- AMOTL2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 68/353 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs765734570, COSV51439072; called by muse, mutect2, varscan2
- BAP1 | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 107/424 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV56243623; called by muse, mutect2, varscan2
- CAMKK2 | c.1188G>A p.M396I | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV61213013; called by muse, mutect2, varscan2
- DYTN | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as rs372283021, COSV65970567; called by mutect2, varscan2
- KMT2C | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 12/88 reads (14%) | catalogued as COSV51484848; called by muse, mutect2, varscan2
- PCDHGA4 | c.1214G>A p.S405N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs1482205004; called by muse, mutect2, varscan2
- RBL2 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs780116712; called by muse, mutect2
- SIGLEC9 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as rs757637187, COSV51583241; called by muse, mutect2, varscan2
- ULK1 | c.2568C>A p.H856Q | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs143735595; called by muse, mutect2, varscan2
- ACKR3 | c.972C>G p.Y324* | Nonsense Mutation (SNP) | VAF 28/150 reads (19%) | called by muse, mutect2, varscan2
- ANK3 | c.10265A>T p.D3422V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CDC40 | c.352G>C p.A118P | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- CDKAL1 | c.1660C>T p.Q554* | Nonsense Mutation (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2, varscan2
- FMN2 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ITIH6 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); called by muse, mutect2
- LRIF1 | c.2099A>T p.H700L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2K4 | c.222_225del p.X74_splice | Splice Site (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- PLEKHM3 | c.248C>A p.T83N | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PTEN | c.20_21insTT p.E7Dfs*2 | Frame Shift Ins (INS) | VAF 65/418 reads (16%) | called by mutect2, pindel, varscan2
- PTEN | c.662dup p.V222Gfs*21 | Frame Shift Ins (INS) | VAF 24/119 reads (20%) | called by mutect2, pindel, varscan2
- TADA1 | c.56dup p.D21Gfs*9 | Frame Shift Ins (INS) | VAF 20/185 reads (11%) | called by mutect2, varscan2
- MEGF8 | c.3540C>T p.D1180= (on ENST00000251268 / NM_001271938.2; = p.D1113= on NM_001410.3) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs371402264; called by muse, mutect2, varscan2
- MPEG1 | c.1311A>T p.R437= | Silent (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- NIBAN2 | c.1608G>T p.T536= | Silent (SNP) | VAF 28/157 reads (18%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.1956C>A p.I652= | Silent (SNP) | VAF 55/164 reads (34%) | catalogued as COSV55341222; called by muse, mutect2, varscan2
- TBC1D9 | c.111C>T p.G37= | Silent (SNP) | VAF 106/357 reads (30%) | catalogued as rs779300579; called by muse, varscan2
- AC092865.4 | chr12:8390653 G>T | 5'Flank (SNP) | VAF 8/24 reads (33%) | catalogued as rs190105354; called by muse, varscan2
- IMPDH2 | c.-23C>T | 5'UTR (SNP) | VAF 32/150 reads (21%) | called by muse, mutect2, varscan2
- KLF3-AS1 | n.702+896C>T | Intron (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- SNORD116-26 | n.26del | RNA (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
